Surgical pathology report (de-identified scan), TCGA case TCGA-J9-A8CM, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Melbourne Health, specimen TCGA-J9-A8CM-01A (Primary Tumor).

[page 1 of 4]
06E

ICD-O-3

Adenocarcinoma, acinar 8140/3

^{path} Adenocarcinoma NOS 8140/3

Site Prostate NOS 061.9
(p) 11/27/13

DOB: .

Sex:

Episode Results

1. - HIST
2. - VOLUMETRIC
3. - SYNOPSIS

Doctor Details

Requesting Doctor:

Copy-To Doctors:

Episode Details

Status:

Results Available

Collection Date:

Reported Date:

Episode:

HISTOPATHOLOGY REPORT

CLINICAL NOTES :

T2c Ca Prostate. PSA 5.2. Bilat G1 9.

MACROSCOPIC :

1. Labelled pt details. A prostate and attached seminal vesicles 60 x 45 x 41 mm and weighing 61 g.

Block designation:

Right apex: A to C. Left apex: D to F

Right base: G to K. Left base: L to P

Apex to base, right: Q to X. Apex to base, left: Y to FF. P32

2. Right pelvic lymph node. Fatty tissue 75 mm with nine nodes. P3

3. Left pelvic lymph node. Fatty tissue 45 mm with five nodes. P1

MICROSCOPIC :

1-3. The sections show multifocal, bilateral, peripheral zone type adenocarcinoma. The index tumour is extensive, bilateral extending from apex to base, Gleason score **5+4=9**, with multifocal lymphovascular and perineural invasion. There is direct and lymphovascular infiltration of both seminal vesicles and multifocal, bilateral extraprostatic extension up to 20 mm at the apex (central)

[page 2 of 4]
with many foci having positive overlying inked pathological margins up to 17 mm at the apex in areas of diathermy change; tumour at the margin includes Gleason pattern 5.

There is a separate small focus of adenocarcinoma at the right apex, Gleason score **3+3=6**. There is focal high grade PIN. There is metastatic carcinoma in one of nine (1/9) right pelvic lymph nodes, 8 mm with focal extraprostatic extension. The five left pelvic lymph nodes are benign.

CONCLUSION:

1-3. Radical prostatectomy and pelvic lymph nodes: Multifocal, bilateral prostatic adenocarcinoma; index tumour bilateral, Gleason 5+4=9; multifocal lymphovascular invasion; bilateral seminal vesicle invasion; multifocal bilateral extraprostatic extension (up to 20 mm) and positive overlying inked pathological margins (up to 17 mm); metastatic carcinoma in one of nine (1/9) right pelvic lymph nodes; left pelvic nodes benign; pT3bN1.

Reported by:

Email:

All Rights Reserved.
hone:

[page 3 of 4]
Episode Results:

Patient Details

DOB:

Sex:

Episode Results

1. - HIST
2. - VOLUMETRIC
3. - SYNOPSIS

Doctor Details

Requesting Doctor:

Copy-To Doctors:

Episode Details

Status:

Results Available

Collection Date:

Reported Date:

Episode:

SYNOPTIC REPORT: CARCINOMA OF PROSTATE

Specimen type : Radical prostatectomy

Tumour type : Index tumour - adenocarcinoma nos

Other tumour foci - adenocarcinoma nos

Gleason score : Index tumour - 5+4=9 (peripheral zone type)

Other tumour foci - 3+3=6 (peripheral zone type)

Site : See volumetric analysis

Unifocal/Multifocal : Multifocal

Perineural invasion : Present; intra and extraprostatic

Lymphovascular invasion : Present; multifocal

Extraprostatic extension : Multifocal bilateral extraprostatic extension up to 20 mm at the apex (central)

Seminal vesicle involvement : Positive; bilateral

Pathological resection margin status : Positive overlying inked pathological margins bilaterally up to 17 mm at the apex (central); Gleason pattern 5 at margins

[page 4 of 4]
Presence of PIN : Focal

Lymph nodes :

Right pelvic: Metastatic carcinoma present in one of nine nodes (1/9), 8 mm with focal extranodal extension

Left pelvic: No malignancy identified in five nodes (0/5)

Tumour Volume :

Peripheral Zone (black): 32.2 cc

Pathologic stage : pT3bN1

Reported by:

Email

All Rights Reserved.

Phone:

HPVAA Discrepancy		/

Source: NCI Genomic Data Commons file db5a83ef-a333-4fe7-ada2-acb91feeb3b7 (TCGA-J9-A8CM.7B7CB375-6046-437F-8513-9F713EA6407A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).